Gene-level copy-number profile of tumor specimen TCGA-D8-A1JT-01A from TCGA case TCGA-D8-A1JT, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.3 years (25,677 days).
Specimen TCGA-D8-A1JT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.3de70cd5-875b-483a-9051-fe3e78038172.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1JT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bb616a08-7b8a-4d76-af51-d7267adc8670

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,607; copy number 2: 36,467; copy number 3: 15,647; copy number 4: 27; copy number 5: 1,539; copy number 6: 11; copy number 8: 936; copy number 9: 585.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1JT-01A-31D-A13J-01): tumor purity 0.88, ploidy 2.41, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,071 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:174,934,947–180,566,523, 100 genes, copy number 5 (broad region; genes not listed).
- chr1:181,317,690–195,763,501, 183 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:196,225,779–248,919,946, 1,186 genes, copy number 5 (broad region; genes not listed).
- chr8:39,902,275–40,897,833, 14 genes, copy number 5 (within-gene range 3–5): IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–9 (broad region; genes not listed).
- chr17:19,215,615–19,336,715, 1 gene, copy number 5 (within-gene range 1–5): EPN2.
- chr17:19,296,596–20,322,973, 50 genes, copy number 5: EPN2-AS1, B9D1, MIR1180, AC124066.1, MAPK7, MFAP4, AC004448.5, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2, SLC47A2, AC005722.3, AC005722.4, ALDH3A1, AC005722.1, ULK2, NDUFB4P3, AC015726.3, AC015726.2, AC015726.1, AKAP10, AC005730.3, AC005730.2, SPECC1, AC005730.1, KCTD9P1, RNU6-258P, AC004702.1, RNU6-1057P.
- chr17:20,323,001–20,341,045, 3 genes, copy number 5: RNU6-467P, AC008088.1, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 4,607. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
